TARGET case TARGET-30-PALDJW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/36d517b7-16e5-5771-ba38-5ad60616961c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 4.9 years (1,772 days); Year of diagnosis: 2001; Days to last follow up: 796 days (2.2 years); INSS stage: Stage 4.
